Surgical pathology report (de-identified scan), TCGA case TCGA-66-2765, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2765-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lower lobe, among others

Clinical diagnosis and question

Space-occupying lesion left lower lobe, with incipient colliquation.

REPORT ON FINDINGS**Macroscopy**

- 1.) Subaortic LN (aortopulmonary window) (station) left: 1.5 cm lesioned grayish-black node of firm consistency, section surfaces dark.
- 2.) Lobar LN (station 12) upper lobe: 2.2 cm lesioned node with dark section surfaces.
- 3.) Left lower lobe: inflated, fixed resected lung tissue after removal of staple suture line measuring 10.5 x 7.5 cm at the base and up to 3 cm in length. A polar region of the pleura shows a lesion or residual adhesion. The central region of the pleura shows a 2 cm area of whitish discoloration with unclear demarcation and a depression-like puckering or retraction, under which there is a moderately solid, pale brownish-white tumor, max. 3.8 cm in size, with relatively clear demarcation, extending to the pleura in the region of the retraction. In the tumor there is an eccentric lacuna, max. 2.8 cm in size, of irregular shape traversed by trabecular structures. Tumor distance from staple suture line at least 0.5 cm. Rest of parenchyma shows a pale subpleural seam up to 0.5 cm wide in parts with slight induration.
- 4.) Paraesophageal LN (station 8): 5 cm string-shaped node with some surrounding tissue, section surfaces largely dark.
- 5.) Prevascular and retrotracheal LN (station 3): 0.6 cm lesioned node with some surrounding tissue.

Examined:

- 1.) and 2.) Rapid section remains and residual material,
- 3.) 3 sections of tumor (partly with pleura and with color-marked resection surface after removal of staple suture line, 2 sections with pale parenchyma,
- 4.) and 5. All material (in 4. lamellated),
- 10 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Re 1.) and 2.) Immediate intraoperative evaluation (): lymph nodes with massive pigment storage and inclusion of tiny anisotropic particles as well as fibrosis of differing degrees, with hyaline thickening in 1.).

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Resected lung tissue shows peripheral focus of a poorly differentiated, predominantly large-cell and partly clear-cell, nonkeratinizing squamous cell carcinoma with the formation of a large central lacuna.

Secondary diagnosis/diagnoses:

Tumor-related chronic inflammation. Respiratory bronchiolitis with slight discontinuous very small focal interstitial fibrosis. Emphysematous stromal remodeling of lung parenchyma with accentuation in the mantle zone. Low-grade anthracotic pigment deposit in the lung parenchyma, local active chronic and fibrosing pleuritis over the tumor. Lymph nodes with marked anthracotic pigment deposit, plaque of a few tiny particles, partly reactive follicular hyperplasia, partly small nodular and extensive hyaline fibrosis.

Remark/addendum:

Since the large lacuna in the tumor is limited by the carcinomatous squamous epithelium, it is questionable whether this arose as a result of tumor resorption. Alternatively there is the possibility of a carcinoma developing in a peripheral bronchocele. On the assumption that this carcinoma is the primary focus and in view of the size and the focal evidence showing minimal invasion of the overlying pleura, the tumor is classified as pT2 pN01 R0, stage 113. C 34.3; M 8070.

Source: NCI Genomic Data Commons file 20cbb40c-dfb1-4119-bac1-70bb93a40d33 (TCGA-66-2765.89C0D8ED-B798-4684-8C7F-1EF75968DF1B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).